FM case AD3518 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Small intestine.
https://portal.gdc.cancer.gov/cases/9aeec2d4-13af-4f28-9b46-7287151503b6

Male, 77.4 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the duodenum; metastasis biopsied or resected from the pancreas. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
